CGCI case BLGSP-71-23-00406 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/839627e7-bd28-4f49-8388-3401e54ab392

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Age at index: 38 years; Vital status: Dead; Days to death: 26 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 38.9 years (14,193 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 25 days; Ann Arbor extranodal involvement: No.
   Pathology details: Bone marrow malignant cells: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 25 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 11.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 759 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 77 kg; Height: 173 cm; BMI: 25.7; CD4 count: 222; Haart treatment indicator: No.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 11: Comorbidities: HIV/AIDS.
- Day 11: Risk factors: HIV/AIDS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00406-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00406-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00406-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00406-01-BCL6: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-HE-1: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-Ki67: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-BCL2: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-CD3: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-CD20: Tissue microarray coordinates: A2,E3,C5.
  Slide BLGSP-71-23-00406-01-CD10: Tissue microarray coordinates: A2,E3,C5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: endoscopic biopsy; Days from index date to tumor sample procurement: -24; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 759; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: BCL6.
